Gene-level copy-number profile of tumor specimen TCGA-CV-6962-01A from TCGA case TCGA-CV-6962, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.0 years (24,103 days).
Specimen TCGA-CV-6962-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.69afcf1b-ef40-4348-8026-42817d50d5ab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-6962-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 831 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/255b92a6-13ea-4c95-ad23-ceb83bfe7076

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 166; copy number 1: 273; copy number 2: 27,243; copy number 3: 9,274; copy number 4: 19,358; copy number 5: 1,557; copy number 6: 1,658; copy number 7: 195; copy number 8: 54; copy number 9: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-6962-01A-11D-1910-01): tumor purity 0.72, ploidy 3.04, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 159 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr4:5,051,480–5,709,548, 5 genes (within-gene range 0–2): STK32B, Y_RNA, RN7SKP275, LINC01587, EVC2.
- chr9:37,915,898–38,069,227, 1 gene (within-gene range 0–4): SHB.
- chr9:38,147,428–43,045,120, 140 genes (broad region; genes not listed).
- chr10:4,987,400–5,107,686, 5 genes (within-gene range 0–2): AKR1C2, AL391427.1, U8, AKR1C3, U8.
- chr10:72,053,294–72,089,032, 2 genes: AC022392.1, SPOCK2.
- chr15:57,375,967–57,550,717, 4 genes (within-gene range 0–2): CGNL1, RNU6-844P, AC025271.3, AC025271.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,478 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:219,409,039–219,459,369, 1 gene, copy number 6: LYPLAL1-AS1.
- chr3:142,596,393–198,222,513, 962 genes, copy number 5–6 (broad region; genes not listed).
- chr7:12,469,621–16,888,885, 50 genes, copy number 5: AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21, DGKB, EEF1A1P26, AC006150.1, GTF3AP5, AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2.
- chr7:16,938,225–16,938,557, 1 gene, copy number 5: AC098592.1.
- chr7:63,556,598–114,075,920, 971 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:145,009,961–148,420,998, 13 genes, copy number 5 (within-gene range 4–5): AC073310.1, RPL7P59, AC004911.1, DPY19L4P2, AC006007.1, AC073308.1, CNTNAP2, AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4.
- chr8:2,493,876–2,623,382, 5 genes, copy number 7: AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1.
- chr8:124,550,784–128,564,679, 63 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr9:112,028,570–112,175,297, 3 genes, copy number 5 (within-gene range 4–5): AL138756.1, SUSD1, RNU6-855P.
- chr11:78,749,250–78,756,480, 1 gene, copy number 5: AP002768.1.
- chr12:42,456,757–42,590,355, 1 gene, copy number 5 (within-gene range 4–5): PRICKLE1.
- chr12:42,615,221–43,572,038, 14 genes, copy number 5: LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2.
- chr14:23,346,306–23,645,639, 20 genes, copy number 6 (within-gene range 4–6): SLC22A17, EFS, AL049829.2, IL25, CMTM5, MYH6, MIR208A, MYH7, AL132855.1, MIR208B, NGDN, ZFHX2-AS1, ZFHX2, AL135999.2, THTPA, AP1G2, AL135999.1, JPH4, AL135999.3, DHRS2.
- chr15:79,559,256–101,933,350, 560 genes, copy number 6 (broad region; genes not listed).
- chr18:20,946,906–37,992,413, 268 genes, copy number 6 (broad region; genes not listed).
- chr20:87,250–26,251,546, 540 genes, copy number 6–8 (broad region; genes not listed).
- chr21:23,065,491–23,131,206, 5 genes, copy number 5: AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1.

Autosomal genes at a single copy (total copy number 1): 273. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
